Somatic mutation profile of tumor specimen MP2PRT-PAUEFP-TMP1-A (aliquot MP2PRT-PAUEFP-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUEFP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,724 days).
Specimen MP2PRT-PAUEFP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81fd147f-7af6-4025-8e78-1de2f46a77bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEFP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEFP-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2080cfed-8151-4834-834f-c7043bd14d93

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 15, Silent 11, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 52/288 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- COL6A5 | c.3863G>A p.R1288Q | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377088930; called by muse, mutect2, varscan2
- CT47B1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 55/620 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs776414588; called by muse, mutect2
- ETV6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765672; called by muse, mutect2
- KIF17 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766334139; called by muse, mutect2, varscan2
- KIF5C | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1414769940; called by muse, mutect2, varscan2
- SLC26A1 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 56/618 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs764924643; called by muse, mutect2
- SLC2A14 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 103/403 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs766115391, COSV61586459; called by muse, mutect2, varscan2
- TCP10L2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs769196423, COSV52084520; called by muse, mutect2, varscan2
- TP53 | c.844_845insCCCC p.R282Pfs*25 | Frame Shift Ins (INS) | VAF 76/489 reads (16%) | catalogued as COSV53688964; called by mutect2, pindel, varscan2
- JPH4 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 68/734 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- LRP6 | c.235_236del p.E79Ifs*2 | Frame Shift Del (DEL) | VAF 118/280 reads (42%) | called by mutect2, varscan2
- PPARGC1A | c.21C>A p.N7K | Missense Mutation (SNP) | VAF 60/471 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RIN1 | c.2062G>T p.A688S | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SULT4A1 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, varscan2
- USH2A | c.3701T>C p.I1234T | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZBTB7C | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 107/864 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ASTN1 | c.2541G>A p.A847= | Silent (SNP) | VAF 43/449 reads (10%) | catalogued as rs778977363, COSV56061983; called by muse, mutect2
- B4GALNT4 | c.2823C>T p.P941= | Silent (SNP) | VAF 90/513 reads (18%) | catalogued as COSV57323173; called by muse, mutect2, varscan2
- BOD1L1 | c.78G>A p.P26= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as rs1223923940; called by muse, mutect2
- C1orf198 | c.771C>T p.N257= | Silent (SNP) | VAF 56/550 reads (10%) | catalogued as rs1000014350, COSV64176062; called by muse, mutect2, varscan2
- DDX42 | c.717C>T p.L239= | Silent (SNP) | VAF 13/273 reads (5%) | called by muse, mutect2
- EPHA10 | c.780C>T p.G260= | Silent (SNP) | VAF 123/505 reads (24%) | catalogued as rs1370581042, COSV100140186; called by muse, mutect2, varscan2
- GPR15 | c.153C>T p.N51= | Silent (SNP) | VAF 83/337 reads (25%) | catalogued as rs1443495562; called by muse, mutect2, varscan2
- PCNT | c.570C>T p.H190= | Silent (SNP) | VAF 118/832 reads (14%) | called by muse, mutect2, varscan2
- SDC3 | c.744G>T p.L248= | Silent (SNP) | VAF 107/436 reads (25%) | called by muse, mutect2, varscan2
- TENM4 | c.2889G>A p.V963= | Silent (SNP) | VAF 31/245 reads (13%) | called by muse, mutect2, varscan2
- ZNF556 | c.858G>A p.P286= | Silent (SNP) | VAF 29/436 reads (7%) | catalogued as rs377206346; called by muse, mutect2
